Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AC3P, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AC3P-TTP1-A (Primary Tumor).

[page 1 of 4]
Surgical/NonGyn Report

Temporary Copy

Case: [REDACTED]
Collected: [REDACTED] +0
Ordered by: [REDACTED]

Page 1 of 1

Patient: [REDACTED]

ID: [REDACTED]

Location: [REDACTED]

DIAGNOSIS

ESOPHAGUS, ENDOSCOPIC BIOPSY:
- ADENOCARCINOMA.

Specimen Description:

Esophageal mass.

Operative Procedure:

EGD.

Patient Information/History/Diagnosis:

Probable esophageal malignancy.

Gross:

The specimen is received in a container labeled [REDACTED] distal esophagus." This container holds five tan pieces of tissue ranging in size from 0.1 to 0.2 cm in maximum dimension. The specimen is submitted entirely labeled [REDACTED].

Microscopic:

The slides are labeled [REDACTED]

The biopsy contains an invasive adenocarcinoma. In this sample, the neoplasm is moderately differentiated.

Staging Form:

Yes.

ELECTRONIC SIGNATURE FOR [REDACTED]

[page 2 of 4]
CT CHEST W/CONTRAST

Result type: CT CHEST W/CONTRAST
Result date: [REDACTED] +2
Result status: Auth (Verified)
Result title: CT CHEST W/CONTRAST
Performed by: [REDACTED] +2
Verified by: [REDACTED] +2
Encounter info: [REDACTED] +2

* Final Report *

Reason For Exam
DYSPHAGIA

READ
CT CHEST WITH CONTRAST

History: Dysphagia.

Technique: Helical images through the chest following intravenous contrast administration

Findings: Calcified granuloma is noted in the lingular segment of the left upper lobe. There is no infiltrate, effusion or pneumothorax. There is no pulmonary mass or nodule. There is a 3.8 cm distal esophageal mass. Extensive retroperitoneal adenopathy is noted in the visualized upper abdomen. Findings are consistent with malignancy and further evaluation with EGD is recommended. PET may also be helpful if indicated. There is a 17 mm subcarinal node. A 19 mm right paratracheal node is also present.

IMPRESSION: Findings highly suspicious for esophageal cancer with significant retroperitoneal and mediastinal adenopathy.

Completed Action List:

Printed by:
Printed on:

Page 1 of 2
(Continued)

RAVE

[page 3 of 4]
Imaging Services

Procedure	Completion Date/Time	Ordering Physician	Accession Number
CT Chest/Abd w/Contrast	[REDACTED]	[REDACTED]	[REDACTED]

Reason for Exam

esophageal ca

+247

Interpretation

CT CHEST AND ABDOMEN WITH INTRAVENOUS CONTRAST

History: Esophageal cancer.

Helical images through the chest and abdomen following oral and intravenous contrast administration.

Findings: Right subclavian venous access port is present. There are tiny bilateral pleural effusions. There is no infiltrate or pneumothorax. No pulmonary mass or nodule is identified. The heart and mediastinum are normal. Small peritracheal and subcarinal nodes are present. No pathologically enlarged mediastinal node is identified. The aorta enhances normally. There is mild thickening of the distal thoracic esophagus. This has slightly decreased since [REDACTED].

The previously identified tiny right pulmonary nodule is barely perceptible on the current examination.

+163

The liver, gallbladder, spleen, pancreas, kidneys and adrenal glands are normal. There is no evidence of bowel obstruction or inflammatory change. There is no hydronephrosis, free intraperitoneal air or fluid. There is increased soft tissue density in the retroperitoneum at the level of the celiac artery. This is consistent with postoperative change and is unchanged since [REDACTED].

+163

IMPRESSION:

1. Slightly decreased thoracic esophageal thickening.
2. No significant change otherwise.
3. Soft tissue stranding around the celiac axis, consistent with postoperative change.

Dictating Physician: [REDACTED]

Releasing Physician: [REDACTED]

Signature Electronic [REDACTED]

Pt. Initials: [REDACTED]

Dictated: [REDACTED]

Transcribed: [REDACTED]

MRN: [REDACTED]
Birthdate: [REDACTED]
SSN: [REDACTED]
Admit Date: [REDACTED]
SERIES/REVOLVING: [REDACTED]

+230

[page 4 of 4]
CT SOFT TISSUE NECK W/CONTRAST

Result type: CT SOFT TISSUE NECK W/CONTRAST
Result date: [REDACTED] +280
Result status: Auth (Verified)
Result title: CT SOFT TISSUE NECK W/CONTRAST
Performed by: [REDACTED]
Verified by: [REDACTED]
Encounter info: [REDACTED]

* Final Report *

Reason For Exam

RT NECK SWELLING

Progression

READ

CT TISSUE VIEWS OF THE NECK WITH IV CONTRAST

Indication for the examination: Esophageal carcinoma

Procedure: Computed sections were obtained from skull base to the upper mediastinum during intravenous administration of IV contrast.

Findings: The skull base, the face, and the upper neck all appear to be within normal limits. The pathology is in the right supraclavicular region. At that point there are 2 large enhancing mass lesions. One is on the order of 26 x 40 mm in size. The jugular and carotid are draped over the anterior portions of this mass. This mass appears to be nodal in origin and would be very consistent with metastatic disease from esophageal carcinoma. The second is just deep to the clavicle and is actually anterior and lateral to the jugular. This mass is about 20 x 27 mm in size. Again it would be very consistent with a metastatic node. The most proximal jugular is somewhat dilated and full giving a nonspecific fullness to the right neck above the larger mass lesion. I presume the largest mass would be very readily palpable. It appears to be distorting the skin margins.

Impression:

Two prominent nodal masses in the right supraclavicular area very consistent with metastatic esophageal carcinoma. Doubt intrinsic pathology to the neck in terms of a primary ENT tumor.

Signature Line

Dictating Physician: [REDACTED]
Releasing Physician: [REDACTED]
Signature Electronically Authorized

Dictated: [REDACTED]

Transcribe [REDACTED]

RAVE

Page 1 of 2
(Continued)

Source: NCI Genomic Data Commons file ddeb580a-a3d8-45a5-87d9-692ce5f23eae (ER0222 ER-AC3P Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).